TCGA case TCGA-J9-A8CN — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Melbourne Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/186d7f36-4e93-4ab2-bc23-95d5cd296656

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,662 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T3a; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason grade tertiary: Pattern 4; Gleason score: 6.
   Pathology details: Consistent pathology review: Yes; Tumor level prostate: Apex / Middle; Zone of origin prostate: Transition zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 54.8 years (20,003 days); Days to diagnosis: 341 days; AJCC pathologic T: T1.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 339 days; Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,237 days (3.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.03 ng/mL (day 963).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-J9-A8CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-J9-A8CN-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-J9-A8CN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: No; Diagnostic mri performed: No; Lymph nodes examined: No; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Stage record, Psa: PSA most recent results: 0.03.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 3; Gleason pattern tertiary: 4.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Partial Laparoscopic Nephrectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,237 days; disease-specific survival: no event (censored), 1,237 days; disease-free interval: no event (censored), 1,237 days; progression-free interval: no event (censored), 1,237 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-J9-A8CN-01A-11D-A34T-01): tumor purity 0.88, ploidy 1.98, whole-genome doublings 0.
